Somatic mutation profile of tumor specimen TCGA-BS-A0TC-01A (aliquot TCGA-BS-A0TC-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 70.0 years (25,560 days).
Specimen TCGA-BS-A0TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b3c512f-c203-4170-9a0e-6e80be2d5d85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TC-10A (Blood Derived Normal), aliquot TCGA-BS-A0TC-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97948970-6e1b-4d3c-bc9a-9f07d28aaf3e

The open-access MAF lists 1,439 somatic variants for this specimen: 1,192 protein-altering or splice-affecting, 207 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 959, Silent 207, Nonsense Mutation 204, Intron 17, Splice Site 14, RNA 12, Splice Region 5, Frame Shift Ins 5, 3'UTR 4, Translation Start Site 4, 5'Flank 4, 3'Flank 2.

Variants (750 of 1,439; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 34/93 reads (37%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7A | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 120/272 reads (44%) | catalogued as rs72554645, CM970130, COSV58447199; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN5 | c.1942C>T p.R648* | Nonsense Mutation (SNP) | VAF 59/153 reads (39%) | catalogued as rs151340621, CM960313, COSV56584423; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.6562C>T p.R2188* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs200497972, COSV63281417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 67/154 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5662T>G p.F1888V | Missense Mutation (SNP) | VAF 41/101 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868094, COSV63868329, COSV63874983; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 53/126 reads (42%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 74/198 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PTEN | c.437T>G p.L146* | Nonsense Mutation (SNP) | VAF 64/150 reads (43%) | hotspot (GDC flag); catalogued as rs786204933, CD104225, COSV64290532, COSV64291883, COSV64294541; ClinVar: pathogenic; called by muse, varscan2
- RB1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 157/410 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen possibly damaging (0.826); catalogued as rs748094394, CM050316, COSV57309827; ClinVar: conflicting interpretations of pathogenicity / likely benign / uncertain significance; called by muse, mutect2, varscan2
- RXYLT1 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as rs397514695, CM134035, COSV54168177; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 76/174 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- AACS | c.1346A>C p.N449T | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99907849; called by muse, mutect2
- ABCA12 | c.7605T>G p.I2535M (on ENST00000272895 / NM_173076.3; = p.I2217M on NM_015657.3) | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV55961240; called by muse, mutect2, varscan2
- ABCA12 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV55961254; called by muse, mutect2, varscan2
- ABCA13 | c.4155G>T p.E1385D | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.775); catalogued as COSV70030785; called by muse, mutect2, varscan2
- ABCA4 | c.5267C>A p.S1756Y | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64674042; called by muse, mutect2, varscan2
- ABCA5 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV67017114; called by muse, mutect2, varscan2
- ABCA6 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs745713208, COSV52636883; called by muse, mutect2, varscan2
- ABCB5 | c.519A>C p.K173N | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51711009; called by muse, mutect2, varscan2
- ABCB7 | c.2038G>A p.D680N (on ENST00000373394 / NM_001271696.3; = p.D681N on NM_004299.6) | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53720236; called by muse, mutect2, varscan2
- ABCC4 | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 67/156 reads (43%) | catalogued as COSV65313328; called by muse, mutect2, varscan2
- ABCC4 | c.1162-1G>T p.X388_splice | Splice Site (SNP) | VAF 46/102 reads (45%) | catalogued as COSV65313332; called by muse, mutect2, varscan2
- ABCC8 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs746071480, COSV56851447; called by muse, mutect2, varscan2
- ABRA | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100357551, COSV61732577; called by muse, mutect2, varscan2
- ABRAXAS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 121/378 reads (32%) | catalogued as rs1300270870, COSV55029469; called by muse, mutect2, varscan2
- AC004593.2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 84/244 reads (34%) | catalogued as COSV56089052; called by muse, mutect2, varscan2
- AC024598.1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs371278525, COSV60824183; called by muse, mutect2, varscan2
- AC126283.2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 65/182 reads (36%) | catalogued as COSV67098824; called by muse, mutect2, varscan2
- AC131160.1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs867682635; called by muse, mutect2, varscan2
- ACADM | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 148/383 reads (39%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.611); catalogued as COSV63720044, COSV63720242; called by muse, mutect2, varscan2
- ACAN | c.6307A>G p.T2103A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV61361723; called by muse, mutect2, varscan2
- ACOT4 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58335707; called by muse, mutect2, varscan2
- ADAMTS12 | c.2428T>C p.Y810H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61264421, COSV61283675; called by muse, mutect2, varscan2
- ADAMTS18 | c.3645G>T p.K1215N | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV51414813, COSV51425227; called by muse, mutect2, varscan2
- ADAMTS19 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as COSV50752182; called by muse, mutect2, varscan2
- ADAMTS20 | c.2420G>T p.R807I | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67125988; called by muse, mutect2, varscan2
- ADAMTS9 | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55775801, COSV55782352; called by muse, mutect2, varscan2
- ADGRG4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs763907204, COSV54954261; called by muse, mutect2, varscan2
- ADGRG4 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV54957577; called by muse, mutect2, varscan2
- ADGRG4 | c.3848C>A p.S1283Y | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs377239456, COSV54957590, COSV54966049; called by muse, mutect2, varscan2
- ADGRL2 | c.1889C>A p.S630Y (on ENST00000370717 / NM_001366005.1; = p.S617Y on NM_012302.4) | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV54669952; called by muse, mutect2, varscan2
- ADNP | c.2818C>A p.H940N | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); catalogued as rs1253478712, COSV62425578; called by muse, mutect2, varscan2
- AFF2 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as rs782175109, COSV60654671; called by muse, mutect2, varscan2
- AFP | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56925417; called by muse, mutect2, varscan2
- AGBL5 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100549019, COSV59936640; called by muse, mutect2, varscan2
- AK9 | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58143321; called by muse, mutect2, varscan2
- AKAP12 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs1269478109, COSV53573329, COSV53576009; called by muse, mutect2, varscan2
- AKAP4 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV62074625; called by muse, mutect2, varscan2
- AKAP9 | c.6830T>G p.L2277* (on ENST00000359028; = p.L2253* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV62347874; called by muse, mutect2, varscan2
- AKAP9 | c.7804T>C p.S2602P (on ENST00000359028; = p.S2578P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV62347889; called by muse, mutect2, varscan2
- AKNAD1 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.875); catalogued as rs758809669, COSV62199129; called by muse, mutect2, varscan2
- AL592490.1 | c.2191C>A p.L731I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.869); catalogued as COSV69426556; called by muse, mutect2, varscan2
- ALDH6A1 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as rs756777014, COSV63246495; called by muse, mutect2, varscan2
- ALG13 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52639707; called by muse, mutect2, varscan2
- ALOX5 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs753136580, COSV65552670; called by muse, mutect2, varscan2
- ALOX5 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs535808410, COSV65552256; called by muse, mutect2, varscan2
- ALX1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as COSV57492068; called by muse, mutect2, varscan2
- AMER1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779222316, COSV57655975; called by muse, mutect2, varscan2
- AMMECR1L | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV55760188, COSV99761263; called by muse, varscan2
- AMY2B | c.495C>A p.N165K | Missense Mutation (SNP) | VAF 150/451 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs752300669, COSV63715468; called by muse, mutect2, varscan2
- ANK3 | c.2675T>C p.L892S (on ENST00000280772 / NM_001320874.2; = p.L26S on NM_001149.3) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55060880; called by muse, mutect2, varscan2
- ANK3 | c.1430G>A p.G477D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55060904; called by muse, mutect2, varscan2
- ANKEF1 | c.2102T>C p.V701A | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV65692568; called by muse, mutect2, varscan2
- ANKFY1 | c.2008G>A p.V670I (on ENST00000341657 / NM_001330063.2; = p.V671I on NM_016376.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs755780066, COSV58918203; called by muse, mutect2, varscan2
- ANKRD12 | c.6139T>C p.Y2047H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV50827049; called by muse, mutect2, varscan2
- ANKRD30A | c.2051C>A p.S684Y (on ENST00000611781; = p.S628Y on NM_052997.2) | Missense Mutation (SNP) | VAF 235/290 reads (81%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.888); catalogued as COSV64607318, COSV64611712; called by muse, mutect2, varscan2
- ANKRD36B | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 62/181 reads (34%) | catalogued as COSV51532855; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ANO4 | c.594C>A p.F198L (on ENST00000392977 / NM_001286615.2; = p.F163L on NM_178826.4) | Missense Mutation (SNP) | VAF 85/193 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV54597694; called by muse, mutect2, varscan2
- ANO5 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 76/209 reads (36%) | catalogued as COSV61085656; called by muse, mutect2, varscan2
- AP3B1 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV54884889, COSV54890106; called by muse, mutect2, varscan2
- AP3M2 | c.1238A>C p.K413T | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1482509450, COSV51529181; called by muse, mutect2, varscan2
- AP4B1 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 26/60 reads (43%) | catalogued as rs762612591, COSV56723465, COSV56726282; called by muse, mutect2
- API5 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 67/178 reads (38%) | catalogued as rs780783169, COSV66633586; called by muse, mutect2, varscan2
- APOB | c.9107C>A p.S3036Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925687; called by muse, mutect2, varscan2
- AQR | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV50035895; called by muse, mutect2, varscan2
- AR | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as rs769445750, COSV65957778; called by muse, mutect2, varscan2
- ARFGEF2 | c.1624C>T p.Q542* | Nonsense Mutation (SNP) | VAF 65/157 reads (41%) | catalogued as COSV64212676; called by muse, mutect2, varscan2
- ARFGEF2 | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 90/232 reads (39%) | catalogued as COSV64212679; called by muse, mutect2, varscan2
- ARHGAP20 | c.2578C>A p.L860I | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV52812414, COSV52815475; called by muse, mutect2, varscan2
- ARHGAP44 | c.1153T>G p.L385V | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52395021; called by muse, mutect2, varscan2
- ARHGEF26 | c.1796A>C p.D599A | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV62847093; called by muse, mutect2, varscan2
- ARHGEF6 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 110/332 reads (33%) | catalogued as rs952314313, COSV51691658; called by muse, mutect2, varscan2
- ARHGEF6 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51688847; called by muse, mutect2, varscan2
- ARHGEF6 | c.1129T>C p.F377L | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51691683; called by muse, mutect2, varscan2
- ARID3C | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52407661; called by muse, mutect2, varscan2
- ARID5B | c.739A>C p.N247H | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54421652; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs757791916, COSV64550311, COSV64551406; called by muse, mutect2, varscan2
- ARMC6 | c.398A>G p.Q133R (on ENST00000392336; = p.Q108R on NM_033415.4) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV54182137; called by muse, mutect2, varscan2
- ARMC9 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63021176; called by muse, mutect2, varscan2
- ARMCX3 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV57870373; called by muse, mutect2, varscan2
- ARMCX5 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55766767; called by muse, mutect2, varscan2
- ARNT2 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV57585925; called by muse, mutect2, varscan2
- ARSF | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV63839800; called by muse, mutect2, varscan2
- ASB15 | c.108-1G>T p.X36_splice | Splice Site (SNP) | VAF 48/169 reads (28%) | catalogued as COSV51926460; called by muse, mutect2, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by muse, mutect2
- ASXL3 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV52467737; called by muse, mutect2, varscan2
- ATAD5 | c.2223G>T p.K741N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV58975307; called by muse, mutect2, varscan2
- ATM | c.8596C>A p.L2866I | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV53748119; called by muse, mutect2, varscan2
- ATP10A | c.3268C>A p.L1090M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100790794, COSV63518248; called by muse, mutect2, varscan2
- ATP10B | c.3396C>A p.F1132L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59153682; called by muse, mutect2, varscan2
- ATP11B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 49/136 reads (36%) | catalogued as rs1423341970, COSV60026312, COSV60030848; called by muse, mutect2, varscan2
- ATP11C | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59565254; called by muse, mutect2, varscan2
- ATP11C | c.1602-1G>T p.X534_splice | Splice Site (SNP) | VAF 63/211 reads (30%) | catalogued as COSV59565289, COSV59566606; called by muse, mutect2, varscan2
- ATP11C | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.039); catalogued as COSV59565325; called by muse, mutect2, varscan2
- ATP13A1 | c.2319G>T p.Q773H | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs771828894, COSV52286695; called by muse, mutect2, varscan2
- ATP1A3 | c.1253C>T p.S418L (on ENST00000545399 / NM_001256214.2; = p.S405L on NM_152296.5) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs368489500; called by muse, mutect2, varscan2
- ATP6V1B1 | c.174+2T>C p.X58_splice | Splice Site (SNP) | VAF 27/68 reads (40%) | catalogued as COSV52269778; called by muse, mutect2, varscan2
- ATP7A | c.368G>T p.R123I | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV58447181; called by muse, mutect2, varscan2
- ATP8B3 | c.3666G>T p.E1222D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as COSV59543365; called by muse, mutect2, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, mutect2, varscan2
- AXIN2 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61057896; called by muse, mutect2, varscan2
- AXL | c.2176T>C p.Y726H (on ENST00000301178 / NM_021913.5; = p.Y717H on NM_001699.6) | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56569013; called by muse, mutect2, varscan2
- B3GNT3 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1468202667, COSV57953271; called by muse, mutect2, varscan2
- B3GNT5 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV58476048; called by muse, mutect2, varscan2
- BAALC | c.514C>T p.R172* (on ENST00000297574 / NM_001364874.1; = p.R137* on NM_024812.3) | Nonsense Mutation (SNP) | VAF 51/120 reads (43%) | catalogued as rs144334771, COSV52561229; called by muse, mutect2, varscan2
- BAAT | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV52289374; called by muse, mutect2, varscan2
- BABAM2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as rs773629059, COSV59624470, COSV59630226, COSV59633919; called by muse, mutect2, varscan2
- BARX2 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV55650635; called by muse, mutect2, varscan2
- BAZ2B | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 100/296 reads (34%) | catalogued as rs749124681, COSV54275727; called by muse, mutect2, varscan2
- BCKDHB | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100243337; called by muse, mutect2
- BCOR | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs367848648, COSV60708819; called by muse, mutect2, varscan2
- BCOR | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60705670; called by muse, mutect2, varscan2
- BEND4 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 51/133 reads (38%) | catalogued as COSV72469138; called by muse, mutect2, varscan2
- BICD2 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs774220760, COSV63549255; called by muse, mutect2, varscan2
- BIK | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as rs545742731, COSV51792648; called by muse, mutect2, varscan2
- BIRC2 | c.758C>A p.S253Y | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV57161166; called by muse, mutect2, varscan2
- BLMH | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480557860, COSV55585417; called by muse, mutect2, varscan2
- BLOC1S5 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV55241687; called by muse, mutect2, varscan2
- BMP5 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100895914, COSV63703584; called by muse, mutect2, varscan2
- BOD1L1 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50015777; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015843, COSV99240474; called by muse, mutect2, varscan2
- BRCA1 | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as COSV58791307; called by muse, mutect2, varscan2
- BRCA2 | c.8223G>T p.K2741N | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV66454818; called by muse, mutect2, varscan2
- BRDT | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62865302; called by muse, mutect2, varscan2
- BRI3BP | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs1458881001, COSV58296294; called by muse, mutect2, varscan2
- BRMS1L | c.834A>C p.K278N | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV53763380; called by muse, mutect2, varscan2
- BTBD10 | c.1034T>G p.F345C | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53399380; called by muse, mutect2, varscan2
- BTBD7 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54135998; called by muse, mutect2, varscan2
- BTK | c.591C>A p.I197= | Splice Region (SNP) | VAF 63/145 reads (43%) | catalogued as COSV58120418; called by muse, mutect2, varscan2
- BTN3A1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV50024886; called by muse, mutect2, varscan2
- C12orf4 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as rs758466065, COSV54206411; called by muse, mutect2, varscan2
- C17orf80 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as rs377133509; called by muse, mutect2, varscan2
- C1R | c.991G>A p.E331K (on ENST00000536053 / NM_001354346.2; = p.E317K on NM_001733.7) | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as rs772306231, COSV73293776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1S | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1565625243, COSV61071065; called by muse, mutect2, varscan2
- C1orf131 | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 159/203 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59642423; called by muse, mutect2, varscan2
- C3AR1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs768607158, COSV50818743, COSV99368193; called by muse, mutect2, varscan2
- C5orf24 | c.225A>C p.K75N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.201); catalogued as COSV57542925; called by muse, mutect2, varscan2
- C8B | c.1552+2T>C p.X518_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as rs1394604123, COSV64777918; called by muse, mutect2, varscan2
- C9 | c.1387A>G p.N463D | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV54677358; called by muse, mutect2, varscan2
- CABS1 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56733093, COSV56733769, COSV99909017; called by muse, mutect2, varscan2
- CACNA1C | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as COSV59725337; called by muse, mutect2, varscan2
- CACNA1D | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 150/388 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV55449172; called by muse, mutect2, varscan2
- CACNA1F | c.3617C>T p.A1206V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV59902975; called by muse, mutect2, varscan2
- CALCRL | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66475296; called by muse, mutect2, varscan2
- CALML5 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1469001444; called by muse, mutect2, varscan2
- CASK | c.2358G>T p.K786N (on ENST00000378163 / NM_001367721.1; = p.K781N on NM_003688.3) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100586892; called by muse, mutect2
- CBLB | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51428155; called by muse, mutect2, varscan2
- CBLL2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs780904588, COSV60369007; called by muse, mutect2, varscan2
- CCDC141 | c.1821G>T p.E607D | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.024); catalogued as COSV55374831; called by muse, mutect2
- CCDC171 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 62/165 reads (38%) | catalogued as COSV52642544; called by muse, mutect2, varscan2
- CCDC173 | c.692G>T p.R231I | Missense Mutation (SNP) | VAF 153/380 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV69573065; called by muse, mutect2, varscan2
- CCDC63 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs761590144, COSV57527007; called by muse, mutect2, varscan2
- CCDC66 | c.1808C>A p.S603Y (on ENST00000394672 / NM_001353147.1; = p.S569Y on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58304738; called by muse, mutect2, varscan2
- CCDC68 | c.830G>T p.R277I | Missense Mutation (SNP) | VAF 115/280 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs1322562293, COSV61603833; called by muse, mutect2, varscan2
- CCDC73 | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV100066337, COSV58799488; called by muse, mutect2, varscan2
- CCDC89 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57034084; called by muse, mutect2, varscan2
- CCNA1 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 85/224 reads (38%) | catalogued as COSV55221943; called by muse, mutect2, varscan2
- CCNB3 | c.998T>A p.L333* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV52074459; called by muse, mutect2, varscan2
- CDC16 | c.1682C>G p.P561R | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV52959827; called by muse, mutect2, varscan2
- CDC7 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as rs763649740, COSV52310879; called by muse, mutect2, varscan2
- CDH10 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs754465931, COSV52569054, COSV52590251; called by muse, mutect2, varscan2
- CDH12 | c.2064A>C p.K688N | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66409679; called by muse, mutect2, varscan2
- CDH4 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs150253018; called by muse, mutect2, varscan2
- CDH7 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 69/196 reads (35%) | catalogued as COSV59887189; called by muse, mutect2, varscan2
- CDRT4 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV56465430; called by muse, mutect2, varscan2
- CEBPZ | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1039861251, COSV50016938; called by muse, mutect2, varscan2
- CENPF | c.5416G>T p.E1806* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV65275441; called by muse, mutect2, varscan2
- CENPH | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV51584908; called by muse, mutect2, varscan2
- CENPO | c.632G>T p.R211I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53166029, COSV99568458; called by muse, mutect2, varscan2
- CEP112 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67140283; called by muse, mutect2, varscan2
- CEP120 | c.2713A>C p.N905H | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV60265979; called by muse, mutect2, varscan2
- CEP120 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 41/71 reads (58%) | catalogued as rs1273417578, COSV60265984; called by muse, mutect2, varscan2
- CEP126 | c.2078C>A p.S693Y | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV54824113; called by muse, mutect2, varscan2
- CEP135 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs746656609, COSV57260542; called by muse, mutect2, varscan2
- CEP250 | c.7318G>A p.A2440T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs748792917, COSV61168911; called by muse, mutect2, varscan2
- CEP290 | c.5980C>T p.L1994F | Missense Mutation (SNP) | VAF 128/344 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.228); catalogued as COSV58352292; called by muse, mutect2, varscan2
- CEP290 | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 40/102 reads (39%) | catalogued as COSV58352298; called by muse, mutect2, varscan2
- CETN2 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 85/215 reads (40%) | catalogued as COSV64744130; called by muse, mutect2, varscan2
- CETN3 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 64/158 reads (41%) | catalogued as COSV51617451; called by muse, mutect2, varscan2
- CFAP251 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); catalogued as rs200832950, COSV56611004; called by muse, mutect2, varscan2
- CFAP43 | c.1278T>G p.I426M | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1389247896, COSV53378248; called by muse, mutect2, varscan2
- CFAP53 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 95/242 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs1284174375, COSV68352059; called by muse, mutect2, varscan2
- CFAP54 | c.5471G>A p.R1824Q | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs558062906, COSV61570271; called by muse, mutect2, varscan2
- CFAP54 | c.7023G>T p.K2341N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.854); catalogued as COSV61572445; called by muse, mutect2, varscan2
- CFAP61 | c.2820G>T p.K940N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55628475, COSV55631689, COSV55648654; called by muse, mutect2, varscan2
- CFHR3 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV66401552; called by muse, mutect2, varscan2
- CHD4 | c.2579A>G p.D860G (on ENST00000357008 / NM_001363606.2; = p.D873G on NM_001273.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58902257; called by muse, mutect2, varscan2
- CHD4 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV58902271; called by muse, mutect2, varscan2
- CHD9 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1490981223, COSV68297628; called by muse, mutect2, varscan2
- CHMP3 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as COSV55685573, COSV99806644; called by muse, mutect2, varscan2
- CHORDC1 | c.424A>C p.N142H | Missense Mutation (SNP) | VAF 152/326 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV57706130; called by muse, mutect2, varscan2
- CIZ1 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV52971759; called by muse, mutect2, varscan2
- CLASP1 | c.2671C>T p.R891* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as COSV55325822; called by muse, mutect2, varscan2
- CLASP2 | c.3248C>T p.A1083V (on ENST00000359576; = p.A1082V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.562); catalogued as COSV56283657; called by muse, mutect2, varscan2
- CLCA1 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs369436125; called by muse, mutect2, varscan2
- CLDN2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61020881, COSV61020917; called by muse, mutect2, varscan2
- CLDND1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57858931; called by muse, mutect2, varscan2
- CLEC4F | c.1386A>C p.Q462H | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV55479726; called by muse, mutect2, varscan2
- CLRN3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs754104842, COSV64098240; called by muse, mutect2, varscan2
- CLSPN | c.3415C>T p.R1139* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as rs1344308365, COSV52051490; called by muse, mutect2, varscan2
- CNGA2 | c.1647C>A p.F549L | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61704802; called by muse, mutect2, varscan2
- CNIH1 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53594541; called by muse, mutect2, varscan2
- CNOT1 | c.4949G>A p.R1650Q | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV55317545; called by muse, mutect2, varscan2
- CNTLN | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs375104473; called by muse, mutect2, varscan2
- CNTLN | c.3006G>T p.K1002N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52080663; called by muse, mutect2, varscan2
- CNTN5 | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 52/114 reads (46%) | catalogued as rs780931539, COSV54291267; called by muse, mutect2, varscan2
- COL10A1 | c.1722T>G p.I574M | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV54573226; called by muse, mutect2, varscan2
- COL11A1 | c.3946G>T p.D1316Y | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1390638679, COSV62185037, COSV62199244; called by muse, mutect2, varscan2
- COL17A1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 56/112 reads (50%) | catalogued as rs774098820, COSV62227127; called by muse, mutect2, varscan2
- COL19A1 | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59570739; called by muse, mutect2, varscan2
- COL24A1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as rs759958666, COSV65303607; called by muse, mutect2, varscan2
- COL4A2 | c.3766C>T p.R1256* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs374366470; called by muse, mutect2, varscan2
- COL4A6 | c.3751C>T p.P1251S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as rs746802079, COSV57868098; called by muse, mutect2, varscan2
- COQ4 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55957176; called by muse, mutect2, varscan2
- CPA6 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | catalogued as rs764322098, COSV52731124, COSV99913777; called by muse, mutect2, varscan2
- CPED1 | c.2752T>G p.L918V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV60003625; called by muse, mutect2, varscan2
- CPSF6 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1185033229, COSV57015114; called by muse, mutect2, varscan2
- CPXM1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144712965; called by muse, mutect2, varscan2
- CREBBP | c.4317C>A p.F1439L | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52125814; called by muse, mutect2, varscan2
- CRTC2 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV57843287; called by muse, mutect2, varscan2
- CRYBG1 | c.4136C>A p.S1379* | Nonsense Mutation (SNP) | VAF 42/105 reads (40%) | catalogued as COSV64811649, COSV64812448; called by muse, mutect2, varscan2
- CRYBG3 | c.6245C>A p.P2082H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51712414; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs148049722, COSV59978358; called by muse, mutect2, varscan2
- CSMD1 | c.10077G>T p.W3359C (on ENST00000520002; = p.W3358C on NM_033225.6) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59331920; called by muse, mutect2, varscan2
- CSMD2 | c.6073C>T p.R2025W | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs199995969, COSV53917921; called by muse, mutect2, varscan2
- CSN3 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as COSV59244198; called by muse, mutect2, varscan2
- CSNK1G3 | c.709C>A p.H237N | Missense Mutation (SNP) | VAF 104/292 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs541069932, COSV62054871; called by muse, mutect2, varscan2
- CSTL1 | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs369157186; called by muse, mutect2, varscan2
- CTAGE6 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV69917442; called by mutect2, varscan2
- CTNND1 | c.2233G>T p.E745* (on ENST00000399050 / NM_001085458.2; = p.E739* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV62382083; called by muse, mutect2, varscan2
- CTSZ | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 70/164 reads (43%) | catalogued as rs776297305, COSV53883553; called by muse, mutect2, varscan2
- CUBN | c.2800G>T p.E934* | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as COSV64717210; called by muse, mutect2, varscan2
- CUEDC2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs773939359, COSV56523198; called by muse, mutect2, varscan2
- CXCL8 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56641040; called by muse, mutect2, varscan2
- CYLC2 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs956648077, COSV66336380; called by muse, mutect2, varscan2
- CYP26B1 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs773830856, COSV50012144; called by muse, mutect2, varscan2
- CYP2A6 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56535608, COSV56537216; called by muse, mutect2, varscan2
- CYP4F12 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs375001752; called by muse, mutect2, varscan2
- CYP4V2 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | catalogued as COSV66505570; called by muse, mutect2, varscan2
- DCAF1 | c.123G>T p.L41F | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60043267; called by muse, mutect2, varscan2
- DCAF4L2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60478562; called by muse, mutect2, varscan2
- DCBLD1 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 69/163 reads (42%) | catalogued as rs866727389, COSV51641759; called by muse, mutect2, varscan2
- DCHS1 | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.109); catalogued as COSV55036407; called by muse, mutect2, varscan2
- DCLK2 | c.1212T>A p.N404K | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56200521, COSV56205251; called by muse, mutect2, varscan2
- DCLRE1C | c.836G>T p.R279I (on ENST00000378278 / NM_001350965.2; = p.R164I on NM_022487.4) | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV63183717; called by muse, mutect2, varscan2
- DDOST | c.835G>A p.G279S (on ENST00000415136; = p.G262S on NM_005216.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.421); catalogued as rs1005246235, COSV100387379; called by muse, mutect2
- DDX21 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV62555773; called by muse, mutect2, varscan2
- DDX23 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.734); catalogued as COSV56398662; called by muse, mutect2, varscan2
- DDX24 | c.1487A>T p.Q496L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV58212663; called by muse, mutect2, varscan2
- DDX25 | c.1125G>T p.E375D | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54990850; called by muse, mutect2, varscan2
- DDX46 | c.448-1G>T p.X150_splice | Splice Site (SNP) | VAF 85/223 reads (38%) | catalogued as COSV62799514; called by muse, mutect2, varscan2
- DDX5 | c.1577T>G p.F526C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.815); catalogued as rs782040676, COSV56749340; called by muse, mutect2, varscan2
- DELE1 | c.1126C>A p.L376I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as rs755517892, COSV52005109; called by muse, mutect2, varscan2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 51/184 reads (28%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DEPDC4 | c.538T>G p.F180V | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV54553730; called by muse, mutect2, varscan2
- DGKB | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV51787257; called by muse, mutect2, varscan2
- DHRS7B | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60887917; called by muse, mutect2, varscan2
- DKC1 | c.1418G>T p.S473I | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV65729672; called by muse, mutect2, varscan2
- DMBX1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63602083; called by muse, mutect2, varscan2
- DMD | c.5443G>A p.D1815N | Missense Mutation (SNP) | VAF 151/383 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV63759156; called by muse, mutect2, varscan2
- DNAAF6 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV60495992, COSV60497334; called by muse, varscan2
- DNAH1 | c.8892G>T p.K2964N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV70229716; called by muse, mutect2
- DNAH10 | c.5846G>A p.R1949Q (on ENST00000409039; = p.R1888Q on NM_207437.3) | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369904884; called by muse, mutect2, varscan2
- DNAH11 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV60945668, COSV60958727; called by muse, mutect2, varscan2
- DNAH5 | c.5653_5671del p.K1885Lfs*27 | Frame Shift Del (DEL) | VAF 65/198 reads (33%) | catalogued as COSV54229241; called by mutect2, pindel, varscan2
- DNAJC10 | c.1799G>T p.R600I | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51139123, COSV51147140; called by muse, mutect2, varscan2
- DNAJC15 | c.450T>G p.H150Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV64872326; called by muse, mutect2, varscan2
- DNER | c.492A>C p.K164N | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV59167821; called by muse, mutect2, varscan2
- DNM1 | c.1674G>T p.E558D | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV57852088; called by muse, mutect2, varscan2
- DNMBP | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs771129840, COSV60626385; called by muse, mutect2, varscan2
- DOCK1 | c.4964C>T p.S1655L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs368031419; called by muse, mutect2, varscan2
- DOCK11 | c.5675C>A p.S1892* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV52240150; called by muse, mutect2, varscan2
- DOCK2 | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56961547; called by muse, mutect2, varscan2
- DOCK7 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 81/221 reads (37%) | catalogued as COSV52007265; called by muse, mutect2, varscan2
- DPP6 | c.468C>A p.F156L (on ENST00000377770 / NM_001364500.2; = p.F94L on NM_001936.5) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1200473847, COSV100127160, COSV59607413; called by muse, mutect2, varscan2
- DPP8 | c.901A>C p.I301L (on ENST00000341861 / NM_001320875.2; = p.I285L on NM_017743.6) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.253); catalogued as COSV100202182; called by muse, mutect2
- DPP9 | c.2443C>T p.H815Y (on ENST00000598800; = p.H844Y on NM_139159.5) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53591662; called by muse, mutect2, varscan2
- DPYSL3 | c.969C>T p.S323= | Splice Region (SNP) | VAF 32/75 reads (43%) | catalogued as rs751007269, COSV100575384, COSV58327214; called by muse, mutect2, varscan2
- DROSHA | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as rs546365755, COSV60777010; called by muse, mutect2, varscan2
- DSCAM | c.3763C>T p.R1255C | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs762623187, COSV68027885; called by muse, mutect2, varscan2
- DSG3 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs370472156, COSV57126751; called by muse, mutect2, varscan2
- DST | c.15544G>A p.E5182K (on ENST00000361203 / NM_001374722.1; = p.E2770K on NM_015548.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55007022, COSV55018193; called by muse, mutect2, varscan2
- DST | c.14978C>A p.S4993Y (on ENST00000361203 / NM_001374722.1; = p.S2581Y on NM_015548.5) | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs531201352, COSV104390747, COSV55018209; called by muse, mutect2, varscan2
- DST | c.12536C>A p.S4179Y (on ENST00000361203 / NM_001374722.1; = p.S1767Y on NM_015548.5) | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54996980; called by muse, mutect2, varscan2
- DST | c.9876G>T p.E3292D | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV55018242; called by muse, mutect2, varscan2
- DUS3L | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57832135; called by muse, mutect2, varscan2
- DUSP16 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); catalogued as COSV53807879; called by muse, mutect2, varscan2
- DYSF | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs761528558, COSV50398533; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYTN | c.1049G>T p.R350I | Missense Mutation (SNP) | VAF 184/455 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV71751932, COSV71752730; called by muse, mutect2, varscan2
- EBNA1BP2 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs774978698, COSV52540214; called by muse, mutect2, varscan2
- ECM2 | c.622A>C p.K208Q | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60740921; called by muse, mutect2, varscan2
- EDRF1 | c.3556G>A p.E1186K (on ENST00000356792 / NM_001202438.2; = p.E1152K on NM_015608.2) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs777464226, COSV61764228; called by muse, mutect2, varscan2
- EEF1A1 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV58549812; called by muse, mutect2, varscan2
- EFCAB13 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 79/177 reads (45%) | catalogued as COSV58949123; called by muse, mutect2, varscan2
- EHHADH | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV51630594; called by muse, mutect2, varscan2
- EIF4E2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs964360849, COSV51472171; called by muse, mutect2, varscan2
- EIF4G1 | c.3652C>T p.R1218W (on ENST00000346169 / NM_198241.3; = p.R1023W on NM_004953.5) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs570589392, COSV59991316; called by muse, mutect2, varscan2
- EIF5A2 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 76/203 reads (37%) | catalogued as COSV55543149; called by muse, mutect2, varscan2
- ELAPOR2 | c.2862A>C p.Q954H (on ENST00000450689 / NM_001142749.3; = p.Q787H on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV51886573; called by muse, mutect2, varscan2
- ELN | c.2130C>A p.Y710* (on ENST00000320399 / NM_001278939.1; = p.Y677* on NM_000501.4) | Nonsense Mutation (SNP) | VAF 28/66 reads (42%) | catalogued as COSV52710959; called by muse, mutect2, varscan2
- ELOVL7 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV70918096; called by muse, mutect2, varscan2
- ELP1 | c.2014A>T p.T672S | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.129); catalogued as COSV65898056; called by muse, mutect2, varscan2
- EML5 | c.5297C>A p.S1766Y (on ENST00000380664; = p.S1774Y on NM_183387.3) | Missense Mutation (SNP) | VAF 13/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100715558, COSV61341356; called by muse, mutect2
- ENAM | c.1402A>C p.K468Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV68536088; called by muse, mutect2, varscan2
- ENGASE | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as rs201772444; called by muse, mutect2, varscan2
- EPB41L3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs750621088, COSV59455576; called by muse, mutect2, varscan2
- EPB41L4A | c.1892C>A p.S631Y | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV54870947; called by muse, mutect2, varscan2
- EPHA7 | c.2086C>A p.H696N | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65183875; called by muse, mutect2, varscan2
- EPHA8 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370576065, COSV51309663; called by muse, mutect2, varscan2
- EPHB1 | c.1839G>T p.E613D | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV67662607, COSV67669226; called by muse, mutect2, varscan2
- EPOR | c.907A>C p.N303H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55800514; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERCC6L | c.3257C>A p.S1086Y | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV57820836; called by muse, mutect2, varscan2
- EREG | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55261472; called by muse, mutect2, varscan2
- ERO1B | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 162/202 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51595910; called by muse, mutect2, varscan2
- ESCO1 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV52520114; called by muse, mutect2, varscan2
- ESPN | c.2295G>T p.K765N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64704519, COSV64705304; called by muse, mutect2, varscan2
- ESR2 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50832362; called by muse, mutect2, varscan2
- ESRP2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779909429, COSV52173814; called by muse, mutect2, varscan2
- ETFRF1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV61477538; called by muse, mutect2, varscan2
- ETNK1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 75/217 reads (35%) | catalogued as COSV56883453; called by muse, mutect2, varscan2
- EXD1 | c.459T>G p.I153M | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59254413; called by muse, mutect2, varscan2
- EXOC3 | c.1520T>G p.L507* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV59266969; called by muse, mutect2, varscan2
- EXOC4 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs199786320, COSV54094022; called by muse, mutect2, varscan2
- EXOC6 | c.780G>T p.L260F | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV53325391; called by muse, mutect2, varscan2
- EXOSC2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 107/246 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV64910641; called by muse, mutect2, varscan2
- EZH2 | c.721A>C p.K241Q | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57454298; called by muse, mutect2, varscan2
- F8 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV64274162; called by muse, mutect2, varscan2
- FABP9 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 82/178 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.29); catalogued as rs749835352, COSV66911575; called by muse, mutect2, varscan2
- FAHD2B | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs541005193; called by muse, mutect2, varscan2
- FAM114A2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61078012; called by muse, mutect2, varscan2
- FAM135A | c.2477G>T p.S826I (on ENST00000370479 / NM_001351599.1; = p.S613I on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52052429; called by muse, mutect2, varscan2
- FAM135B | c.3298G>T p.E1100* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV52711010, COSV52728944; called by muse, mutect2, varscan2
- FAM135B | c.2309C>T p.S770F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52728961; called by muse, mutect2, varscan2
- FAM209B | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100990944; called by muse, mutect2
- FAM47B | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV61454305; called by muse, mutect2, varscan2
- FANCB | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 126/285 reads (44%) | catalogued as COSV60760068; called by muse, mutect2, varscan2
- FANCB | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1354970109, COSV60760083; called by muse, mutect2, varscan2
- FANCB | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1057515809, COSV60759290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCM | c.3158C>A p.S1053* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV57501920, COSV57504659; called by muse, mutect2, varscan2
- FAP | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as rs1352355630, COSV51862475; called by muse, mutect2, varscan2
- FARSA | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.947); catalogued as COSV58905051; called by muse, mutect2, varscan2
- FARSB | c.432G>T p.E144D | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs749096938, COSV56049957; called by muse, mutect2, varscan2
- FAS | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58238960; called by muse, mutect2, varscan2
- FAT1 | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV71674428; called by muse, mutect2, varscan2
- FAT4 | c.14122T>G p.F4708V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV58688549; called by muse, mutect2, varscan2
- FBN1 | c.6872-1G>T p.X2291_splice | Splice Site (SNP) | VAF 29/81 reads (36%) | catalogued as CS161893, COSV57318634; called by muse, mutect2, varscan2
- FBN2 | c.6747G>T p.M2249I | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52517356; called by muse, mutect2, varscan2
- FBXO17 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV53069903; called by muse, mutect2, varscan2
- FBXO4 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55851822; called by muse, mutect2, varscan2
- FBXO43 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV71053747, COSV71054194; called by muse, mutect2, varscan2
- FBXW7 | c.744G>T p.E248D (on ENST00000281708 / NM_001349798.2; = p.E168D on NM_018315.5) | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV55921179; called by muse, mutect2, varscan2
- FCN1 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65662457, COSV65662875; called by muse, mutect2, varscan2
- FFAR3 | c.285C>A p.F95L | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59909135; called by muse, mutect2, varscan2
- FGB | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.433); catalogued as COSV57418626; called by muse, mutect2, varscan2
- FGG | c.123C>T p.F41= | Splice Region (SNP) | VAF 54/117 reads (46%) | catalogued as rs141554929; called by muse, mutect2, varscan2
- FIG4 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57788075; called by muse, mutect2, varscan2
- FLCN | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs777826268, COSV53259789; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- FLRT2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1294144428, COSV58141988, COSV58142679; called by muse, mutect2, varscan2
- FLT3 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 77/180 reads (43%) | catalogued as COSV54043825, COSV54056063; called by muse, mutect2, varscan2
- FOS | c.1088G>A p.S363N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as rs764583472, COSV57839660; called by muse, mutect2, varscan2
- FOXM1 | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100700908, COSV61206202; called by muse, mutect2, varscan2
- FOXR2 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1185678786, COSV59258623; called by muse, mutect2, varscan2
- FRAS1 | c.3676C>A p.L1226I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53606466; called by muse, mutect2, varscan2
- FRAS1 | c.10512C>A p.F3504L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53615409; called by muse, mutect2, varscan2
- FREM2 | c.8947C>A p.L2983I | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs1336042547, COSV54839857; called by muse, mutect2, varscan2
- FRMD3 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV58462622; called by muse, mutect2, varscan2
- FRMD7 | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV53746529; called by muse, mutect2, varscan2
- FRS3 | c.656T>G p.F219C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as COSV52485098; called by muse, mutect2, varscan2
- FTCD | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201753824, COSV52426509; ClinVar: uncertain significance; called by muse, mutect2
- FUNDC1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 198/501 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV65181501; called by muse, mutect2, varscan2
- FYB1 | c.1846T>G p.F616V | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV60947933; called by muse, mutect2, varscan2
- FYB2 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | catalogued as COSV58583834, COSV58588477; called by muse, mutect2
- FZD6 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs143405641; called by muse, mutect2, varscan2
- G2E3 | c.1033A>C p.N345H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52840687; called by muse, mutect2, varscan2
- G6PC2 | c.1014C>A p.F338L | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1439235691, COSV56372243; called by muse, mutect2, varscan2
- GAB3 | c.1025G>T p.R342I | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV65819775; called by muse, mutect2, varscan2
- GABRA1 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 83/190 reads (44%) | catalogued as COSV50101979, COSV50106468; called by muse, mutect2, varscan2
- GABRA3 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64799559; called by muse, mutect2, varscan2
- GABRB3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs144496462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG2 | c.1394G>A p.R465Q (on ENST00000361925 / NM_001375343.1; = p.R425Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.411); catalogued as rs774474550, COSV100729700, COSV62715569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAD2 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52155737, COSV52158725; called by muse, mutect2, varscan2
- GAL3ST4 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV57585248, COSV57586618; called by muse, mutect2, varscan2
- GALR2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV57163618; called by muse, mutect2
- GANC | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 69/201 reads (34%) | catalogued as COSV58809308; called by muse, mutect2, varscan2
- GAS6 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV59851072; called by muse, mutect2, varscan2
- GBE1 | c.677G>T p.R226I | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV70099757; called by muse, mutect2, varscan2
- GCC2 | c.3430G>T p.E1144* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV100565267, COSV59176843; called by muse, mutect2, varscan2
- GCFC2 | c.2038C>T p.R680C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773928373, COSV58080676; called by muse, mutect2, varscan2
- GCFC2 | c.823T>G p.L275V | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV58081343; called by muse, mutect2, varscan2
- GDF3 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV61712621; called by muse, mutect2, varscan2
- GEN1 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV58056856; called by muse, mutect2, varscan2
- GFRAL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 168/435 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV61231407, COSV61232771; called by muse, mutect2, varscan2
- GFRAL | c.1033C>A p.H345N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs753873571, COSV61231413, COSV61231877; called by muse, mutect2, varscan2
- GINM1 | c.122A>C p.D41A | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV66389891; called by muse, mutect2, varscan2
- GK2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1321996211, COSV62626188; called by muse, mutect2, varscan2
- GLA | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as CD123321, COSV54509366, COSV54510581; called by muse, mutect2, varscan2
- GLB1L3 | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV68392869; called by muse, mutect2, varscan2
- GLDC | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as rs1332097221, COSV58680663; called by muse, mutect2, varscan2
- GLT1D1 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as COSV55882678; called by muse, mutect2, varscan2
- GNAT2 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63554872, COSV63555001; called by muse, mutect2, varscan2
- GPAT3 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 65/197 reads (33%) | catalogued as COSV52355197; called by muse, mutect2, varscan2
- GPAT4 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 50/133 reads (38%) | catalogued as rs758473461, COSV67840743, COSV67841812; called by muse, mutect2, varscan2
- GPR55 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs774169195, COSV67407495; called by muse, mutect2, varscan2
- GPX5 | c.440A>C p.K147T | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); catalogued as COSV69079465; called by muse, mutect2, varscan2
- GRB14 | c.482-1G>A p.X161_splice | Splice Site (SNP) | VAF 61/160 reads (38%) | catalogued as COSV55738708; called by muse, mutect2, varscan2
- GRIK1 | c.2033G>T p.R678I | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58719715; called by muse, mutect2, varscan2
- GRIK3 | c.1824C>A p.F608L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66140622; called by muse, mutect2, varscan2
- GRIN3A | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs962561406, COSV62451945; called by muse, mutect2, varscan2
- GRM3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64471156; called by muse, mutect2
- GRM7 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs776509613, COSV63132276; called by muse, mutect2, varscan2
- GRXCR1 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.359); catalogued as COSV67672052; called by muse, mutect2, varscan2
- GSK3B | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 81/185 reads (44%) | catalogued as COSV51775228; called by muse, mutect2, varscan2
- GSTA5 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 182/492 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs556406136, COSV52862404; called by muse, mutect2, varscan2
- GUCY1A2 | c.2032T>C p.S678P | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs184165416, COSV56488472; called by muse, mutect2, varscan2
- GXYLT1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as COSV55137278; called by muse, mutect2, varscan2
- GYS2 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 67/187 reads (36%) | catalogued as COSV53924038; called by muse, mutect2, varscan2
- H3C3 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); catalogued as COSV63551044; called by muse, mutect2, varscan2
- HACD1 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV63516489; called by muse, mutect2, varscan2
- HACD2 | c.630C>A p.F210L | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as COSV67322076, COSV67322391; called by muse, mutect2
- HACE1 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV53503023; called by muse, mutect2, varscan2
- HCAR2 | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV61025022; called by muse, mutect2, varscan2
- HDX | c.1812C>A p.F604L | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52974943; called by muse, mutect2, varscan2
- HDX | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV52977449; called by muse, mutect2, varscan2
- HECTD1 | c.3184A>C p.N1062H | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1455290943, COSV67946682; called by muse, mutect2, varscan2
- HEG1 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 101/212 reads (48%) | catalogued as COSV60762716; called by muse, mutect2, varscan2
- HELZ2 | c.7453G>A p.E2485K (on ENST00000467148 / NM_001037335.2; = p.E1916K on NM_033405.3) | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.27); catalogued as rs368451665; called by muse, varscan2
- HEPH | c.2775C>A p.F925L (on ENST00000343002; = p.F658L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100294900; called by muse, mutect2
- HEPHL1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1565360317, COSV59892403; called by muse, mutect2, varscan2
- HERC4 | c.2266G>T p.E756* (on ENST00000395198 / NM_022079.3; = p.E748* on NM_015601.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 69/150 reads (46%) | catalogued as COSV53272008; called by muse, mutect2, varscan2
- HFM1 | c.3218G>A p.S1073N | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as COSV54028479; called by muse, mutect2, varscan2
- HFM1 | c.128C>A p.S43* | Nonsense Mutation (SNP) | VAF 92/218 reads (42%) | catalogued as COSV54028493; called by muse, mutect2, varscan2
- HHEX | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV51106283; called by muse, mutect2, varscan2
- HMCN1 | c.5119C>T p.R1707* | Nonsense Mutation (SNP) | VAF 56/76 reads (74%) | catalogued as COSV54899014; called by muse, mutect2, varscan2
- HPD | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 37/102 reads (36%) | catalogued as COSV56642140, COSV99999975; called by muse, mutect2, varscan2
- HRC | c.2046C>A p.F682L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV53255602; called by muse, mutect2
- HRNR | c.236T>C p.F79S | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64258882; called by muse, mutect2, varscan2
- HSD17B12 | c.134T>A p.V45D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV53500112; called by muse, mutect2, varscan2
- HSP90AB1 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV62334838; called by muse, mutect2, varscan2
- HSP90B1 | c.2341G>T p.E781* | Nonsense Mutation (SNP) | VAF 132/335 reads (39%) | catalogued as COSV55355297, COSV55355769; called by muse, mutect2, varscan2
- HTATSF1 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54479184, COSV54481776; called by muse, mutect2, varscan2
- HYOU1 | c.2881G>T p.E961* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as COSV68215962; called by muse, mutect2, varscan2
- IBTK | c.533A>C p.Y178S | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.986); catalogued as COSV60393275; called by muse, mutect2, varscan2
- IFI44L | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV60727868; called by muse, mutect2, varscan2
- IFIT2 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV51079174; called by muse, mutect2, varscan2
- IFNA6 | c.512T>G p.I171S | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101207005, COSV66506471; called by muse, mutect2, varscan2
- IFT74 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66287236; called by muse, mutect2, varscan2
- IGF1 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV61032796; called by muse, mutect2, varscan2
- IGF1R | c.1377T>G p.I459M | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51294949; called by muse, mutect2, varscan2
- IGF2BP3 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51685693; called by muse, mutect2, varscan2
- IKZF1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs1265571297, COSV100498126, COSV58786494; called by muse, mutect2, varscan2
- IL5 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as rs747193100, COSV51504656; called by muse, mutect2, varscan2
- IL6ST | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV61141090; called by muse, mutect2, varscan2
- IMPG1 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64055621; called by mutect2, varscan2
- ING1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58167150, COSV58169034; called by muse, mutect2, varscan2
- INPP4B | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as rs757219824, COSV53710728; called by muse, mutect2, varscan2
- IQGAP2 | c.1521+1G>T p.X507_splice | Splice Site (SNP) | VAF 74/206 reads (36%) | catalogued as COSV56970856; called by muse, mutect2, varscan2
- IRAK3 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV54162240; called by muse, mutect2, varscan2
- ITGA4 | c.2492C>A p.S831Y | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.771); catalogued as rs1459164153, COSV67896622, COSV67897230; called by muse, mutect2, varscan2
- ITGA6 | c.1736G>A p.R579Q (on ENST00000442250; = p.R540Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs1005704533, COSV51221926; called by muse, mutect2, varscan2
- ITGA6 | c.2689G>T p.E897* (on ENST00000442250; = p.E858* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 58/126 reads (46%) | catalogued as COSV51219832; called by muse, mutect2, varscan2
- ITGAD | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs767511529, COSV66758313; called by muse, mutect2, varscan2
- ITGAE | c.316-1G>T p.X106_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53996183, COSV99560572; called by muse, mutect2
- ITGB2 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV56610471; called by muse, mutect2, varscan2
- ITIH5 | c.2009G>T p.R670I | Missense Mutation (SNP) | VAF 126/342 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV53661806; called by muse, mutect2, varscan2
- ITPKB | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV55262707; called by muse, mutect2, varscan2
- ITPR2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 219/531 reads (41%) | catalogued as rs998456358, COSV67270136; called by muse, mutect2, varscan2
- ITPRID1 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV60075678; called by muse, mutect2, varscan2
- JAK1 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs748142963, COSV61091847; called by muse, mutect2, varscan2
- JAKMIP2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs934467542, COSV54599978; called by muse, mutect2, varscan2
- JMJD1C | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs376167675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KANSL1 | c.1010C>A p.S337Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52264702, COSV52267293, COSV99294174; called by muse, mutect2, varscan2
- KAT6A | c.4708G>A p.D1570N | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55906756; called by muse, mutect2, varscan2
- KATNBL1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 93/257 reads (36%) | catalogued as COSV56623619; called by muse, mutect2, varscan2
- KCNA7 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as rs762119570, COSV55503557; called by muse, mutect2, varscan2
- KCNAB1 | c.1160G>A p.G387D (on ENST00000490337 / NM_172160.3; = p.G376D on NM_003471.3) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV56746449; called by muse, mutect2, varscan2
- KCND2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 30/75 reads (40%) | catalogued as COSV100479148, COSV58570890; called by muse, mutect2, varscan2
- KCNJ14 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs745540997, COSV60737739; called by muse, mutect2, varscan2
- KCNMA1 | c.855T>G p.I285M | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54252455; called by muse, mutect2, varscan2
- KCNN4 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV53455758; called by muse, mutect2, varscan2
- KDR | c.3159T>G p.I1053M | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55766564; called by muse, mutect2, varscan2
- KEL | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62333005; called by muse, mutect2, varscan2
- KIAA1109 | c.13312C>T p.R4438C | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375194535, COSV52675740, COSV99166593; called by muse, mutect2, varscan2
- KIF11 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.24); catalogued as COSV53268524; called by muse, mutect2, varscan2
- KIF4B | c.1210C>A p.R404S | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV70528834, COSV70529680; called by muse, mutect2, varscan2
- KIF5A | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54055183, COSV54057601; called by muse, mutect2, varscan2
- KLF10 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.259); catalogued as rs749961016, COSV53435224; called by muse, mutect2, varscan2
- KLHL13 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV53248647; called by muse, mutect2, varscan2
- KLHL28 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.138); catalogued as COSV61888305; called by muse, mutect2, varscan2
- KLHL4 | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV100910329; called by muse, mutect2
- KLRC1 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV61724848; called by muse, mutect2, varscan2
- KMT2C | c.5754T>G p.N1918K | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100068876; called by muse, mutect2
- KMT2D | c.16479A>C p.K5493N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56447127; called by muse, mutect2, varscan2
- KNG1 | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.236); catalogued as COSV53978356; called by muse, mutect2, varscan2
- KNTC1 | c.4012C>T p.R1338C | Missense Mutation (SNP) | VAF 150/371 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752336311, COSV61080208; called by muse, mutect2, varscan2
- KPNA3 | c.1455C>A p.F485L | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV55505099; called by muse, mutect2, varscan2
- KRT37 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs570969356; called by muse, mutect2, varscan2
- KRT4 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53407733, COSV99542905; called by muse, mutect2, varscan2
- KTN1 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV68023729; called by muse, mutect2, varscan2
- L1TD1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV63133554; called by muse, mutect2, varscan2
- L1TD1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV63133557, COSV63134025; called by muse, mutect2, varscan2
- L1TD1 | c.2016A>C p.E672D | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.801); catalogued as COSV63133560; called by muse, mutect2, varscan2
- LAMA2 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV70348755; called by muse, mutect2, varscan2
- LAMA2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV70348760; called by muse, mutect2, varscan2
- LAMA2 | c.5192A>C p.K1731T | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.66); catalogued as rs1273327313, COSV70348765; called by muse, mutect2, varscan2
- LAMA4 | c.4950C>A p.Y1650* (on ENST00000230538 / NM_001105206.3; = p.Y1643* on NM_002290.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as COSV57898093; called by muse, mutect2, varscan2
- LAMA4 | c.4492C>T p.R1498C (on ENST00000230538 / NM_001105206.3; = p.R1491C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs782368185, COSV57898099; called by muse, mutect2, varscan2
- LAS1L | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs145897105, COSV56707584; called by muse, mutect2, varscan2
- LBP | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs1179478330, COSV54140714, COSV99028030; called by muse, mutect2, varscan2
- LBR | c.143A>C p.E48A | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV55289253; called by muse, mutect2, varscan2
- LCA5 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 123/330 reads (37%) | catalogued as COSV100878119, COSV63971619; called by muse, mutect2, varscan2
- LCA5 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 156/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754950803, COSV63971334, COSV63972740; called by muse, mutect2, varscan2
- LCE2D | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 41/52 reads (79%) | catalogued as COSV64229035; called by muse, mutect2, varscan2
- LCLAT1 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.978); catalogued as COSV58373758; called by muse, mutect2, varscan2
- LDLRAP1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs781711827, COSV65473318, COSV65473558; called by muse, mutect2, varscan2
- LEXM | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs763509919, COSV64022925; called by muse, mutect2, varscan2
- LGI2 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as rs139886364; called by muse, mutect2, varscan2
- LGSN | c.1502G>T p.R501I | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs753479275, COSV65727386; called by muse, mutect2, varscan2
- LIPE | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV54923157; called by muse, mutect2, varscan2
- LMAN2L | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53841918; called by muse, mutect2, varscan2
- LMLN | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); catalogued as rs953993488, COSV57599468; called by muse, mutect2, varscan2
- LMOD3 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 81/219 reads (37%) | catalogued as COSV101341970, COSV70456174; called by muse, mutect2, varscan2
- LPAR4 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV70912738; called by muse, mutect2, varscan2
- LRIT3 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs1157741703, COSV59985720, COSV59986898; called by muse, mutect2, varscan2
- LRP1B | c.3679G>T p.V1227L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV67227663; called by muse, mutect2, varscan2
- LRRC1 | c.742T>G p.L248V | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63829310; called by muse, mutect2, varscan2
- LRRC17 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV50864979; called by muse, mutect2, varscan2
- LRRC17 | c.1172_1173insT p.K391Nfs*4 | Frame Shift Ins (INS) | VAF 30/99 reads (30%) | catalogued as COSV99978281; called by mutect2, pindel, varscan2
- LRRC2 | c.457A>C p.K153Q | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56126385; called by muse, mutect2, varscan2
- LRRC25 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV59115176; called by muse, mutect2, varscan2
- LRRC74A | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs779028912, COSV53607822; called by muse, mutect2, varscan2
- LRRFIP1 | c.412G>T p.E138* (on ENST00000392000 / NM_001137552.2; = p.E266* on NM_001137550.2) | Nonsense Mutation (SNP) | VAF 70/210 reads (33%) | catalogued as COSV55252417; called by muse, mutect2, varscan2
- LRRIQ1 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV67812909; called by muse, mutect2, varscan2
- LRRIQ1 | c.3383C>A p.S1128Y | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs1430590892, COSV67831672; called by muse, mutect2, varscan2
- LRRTM2 | c.60G>T p.M20I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99217695; called by muse, mutect2
- LRRTM3 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63662643, COSV63663752; called by muse, mutect2, varscan2
- LTF | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs563355635, COSV51608590; called by muse, mutect2, varscan2
- LUC7L3 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.988); catalogued as COSV53587316; called by muse, mutect2, varscan2
- LY75 | c.5113C>T p.R1705* | Nonsense Mutation (SNP) | VAF 43/113 reads (38%) | catalogued as rs139579850; called by muse, mutect2, varscan2
- LY75 | c.3965C>A p.S1322Y | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55106696, COSV99717189; called by muse, mutect2, varscan2
- LY96 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 112/283 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs1372809531, COSV53025587; called by muse, mutect2, varscan2
- LYSMD4 | c.394G>T p.E132* (on ENST00000409796 / NM_001284417.2; = p.E133* on NM_152449.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as rs752330835, COSV60386126, COSV60387816; called by muse, mutect2, varscan2
- MACF1 | c.8601A>C p.K2867N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as COSV57124338; called by muse, mutect2, varscan2
- MACROD2 | c.867C>A p.N289K (on ENST00000642719; = p.N261K on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53993423, COSV99424879; called by muse, mutect2, varscan2
- MAGEB2 | c.873T>G p.F291L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100975611; called by muse, mutect2
- MAGEB4 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV66775846; called by muse, mutect2, varscan2
- MAGEC1 | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99595133; called by muse, mutect2
- MAGED2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54497414; called by muse, mutect2
- MAGED2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); catalogued as COSV54498034; called by muse, mutect2, varscan2
- MAMDC2 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | catalogued as COSV65858384; called by muse, mutect2, varscan2
- MAML3 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs747076119, COSV72208493; called by muse, mutect2, varscan2
- MAN2A1 | c.3072C>A p.F1024L | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54852509; called by mutect2, varscan2
- MANBA | c.1942C>A p.H648N (on ENST00000642252; = p.H602N on NM_005908.4) | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV56965795, COSV99898456; called by muse, mutect2, varscan2
- MANBA | c.1338C>A p.F446L (on ENST00000642252; = p.F400L on NM_005908.4) | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56965807; called by muse, mutect2, varscan2
- MAP1A | c.4331A>G p.E1444G | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV55809421; called by muse, mutect2, varscan2
- MAP1B | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57097528; called by muse, mutect2, varscan2
- MAP3K1 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 85/218 reads (39%) | catalogued as COSV68124159; called by muse, mutect2, varscan2
- MAP3K1 | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV68124161; called by muse, mutect2, varscan2
- MAP3K19 | c.3135G>T p.K1045N | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs557761734, COSV59639360; called by muse, mutect2, varscan2
- MAP3K19 | c.3037G>T p.E1013* | Nonsense Mutation (SNP) | VAF 114/251 reads (45%) | catalogued as COSV59638929; called by muse, mutect2, varscan2
- MAP4K3 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.027); catalogued as rs764250055, COSV55712676; called by muse, mutect2, varscan2
- MAP4K3 | c.2058A>C p.K686N | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55713731; called by muse, mutect2, varscan2
- MAP7D3 | c.1670C>T p.T557I | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60171139; called by muse, mutect2, varscan2
- MAP7D3 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770927420, COSV60171145; called by muse, mutect2, varscan2
- MARCHF7 | c.150T>G p.Y50* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV52029089; called by muse, mutect2, varscan2
- MBD1 | c.1105C>T p.R369C (on ENST00000269468 / NM_001323950.1; = p.R346C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53998236; called by muse, mutect2, varscan2
- MCEMP1 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58040075; called by muse, mutect2, varscan2
- MCF2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV58486466; called by muse, mutect2, varscan2
- MCF2L2 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs780301597, COSV61054485; called by muse, mutect2, varscan2
- MCM3AP | c.5822C>T p.A1941V | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs17183403, COSV52438683; called by muse, mutect2, varscan2
- MCOLN3 | c.1455C>A p.F485L | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62014472; called by muse, mutect2, varscan2
- MCTP1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 123/295 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56518217; called by muse, mutect2, varscan2
- MED23 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1267288026, COSV100644827, COSV100645221; called by muse, mutect2
- MEIOB | c.779-1G>T p.X260_splice | Splice Site (SNP) | VAF 69/199 reads (35%) | catalogued as rs758581396, COSV58054311; called by muse, mutect2, varscan2
- MEMO1 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54452673; called by muse, mutect2, varscan2
- MGA | c.6652G>T p.E2218* (on ENST00000219905 / NM_001164273.1; = p.E2009* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 63/141 reads (45%) | catalogued as COSV54955269; called by muse, mutect2, varscan2
- MICU3 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 73/181 reads (40%) | catalogued as rs1333364327, COSV58844852; called by muse, mutect2, varscan2
- MIPEP | c.811T>G p.F271V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66299760, COSV66300783; called by muse, mutect2, varscan2
- MIS18BP1 | c.2521G>T p.E841* | Nonsense Mutation (SNP) | VAF 158/367 reads (43%) | catalogued as COSV60371215, COSV60373092; called by muse, mutect2, varscan2
- MKI67 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 77/167 reads (46%) | catalogued as COSV64074756; called by muse, mutect2, varscan2
- MLF1 | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 102/262 reads (39%) | catalogued as COSV63033896; called by muse, mutect2, varscan2
- MMP19 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100491003; called by muse, mutect2
- MNS1 | c.1014A>C p.E338D | Missense Mutation (SNP) | VAF 174/472 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as COSV53068580; called by muse, varscan2
- MOCS2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs766166640, COSV56858259; called by muse, mutect2, varscan2
- MON2 | c.4964C>A p.S1655* | Nonsense Mutation (SNP) | VAF 44/140 reads (31%) | catalogued as COSV54808254; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3301G>T p.D1101Y | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1187518040, COSV56620413; called by muse, varscan2
- MRFAP1L1 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); catalogued as COSV57923157; called by muse, mutect2, varscan2
- MRPL1 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59674107; called by muse, mutect2, varscan2
- MS4A4A | c.371G>T p.R124I | Missense Mutation (SNP) | VAF 233/559 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV59701475; called by muse, mutect2, varscan2
- MS4A8 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1426906759, COSV55753305; called by muse, mutect2, varscan2
- MSH4 | c.2141G>T p.R714I | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54195810, COSV54198926; called by muse, mutect2, varscan2
- MSL1 | c.1623G>T p.K541N (on ENST00000398532 / NM_001365919.1; = p.K278N on NM_001012241.2) | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); catalogued as COSV59899287; called by muse, mutect2, varscan2
- MTFR1L | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1340028673, COSV65355963; called by muse, mutect2, varscan2
- MTM1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100080665, COSV60333518; called by muse, mutect2, varscan2
- MTPAP | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs1564519374, COSV53933458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS1 | c.1988G>A p.S663N | Missense Mutation (SNP) | VAF 137/354 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV50560479; called by muse, mutect2, varscan2
- MUC16 | c.18458A>C p.K6153T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.065); catalogued as COSV67470371; called by muse, mutect2, varscan2
- MUC7 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 277/690 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV59218603; called by muse, mutect2, varscan2
- MYBL1 | c.143A>C p.K48T | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV72918994; called by muse, mutect2, varscan2
- MYBL2 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV53830413; called by muse, mutect2, varscan2
- MYCBP2 | c.2168G>T p.W723L (on ENST00000357337; = p.W761L on NM_015057.5) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV62021662; called by muse, mutect2, varscan2
- MYH11 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 90/229 reads (39%) | catalogued as COSV55548501; called by muse, mutect2, varscan2
- MYH6 | c.4461G>T p.K1487N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62451326; called by muse, mutect2, varscan2
- MYO3A | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 51/132 reads (39%) | catalogued as COSV56333245; called by muse, mutect2, varscan2
- MYO3B | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1037042011, COSV58702263; called by muse, mutect2, varscan2
- MYO5A | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762594836, COSV62560863; called by muse, mutect2, varscan2
- MYOCD | c.374dup p.N125Kfs*16 | Frame Shift Ins (INS) | VAF 31/78 reads (40%) | catalogued as rs1567587048; called by mutect2, varscan2
- MYOM3 | c.2878G>T p.E960* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as COSV58394788, COSV58397208; called by muse, mutect2, varscan2
- MYPN | c.3103A>G p.M1035V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs201975081, COSV62734597; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYSM1 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV68977566; called by muse, mutect2, varscan2
- MYT1L | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 184/492 reads (37%) | catalogued as COSV67702705, COSV67704959; called by muse, mutect2, varscan2
- NAA15 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV56720049; called by muse, mutect2, varscan2
- NAA16 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 37/124 reads (30%) | catalogued as COSV65065349; called by muse, mutect2, varscan2
- NAA25 | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs772144016, COSV55704679; called by muse, mutect2, varscan2
- NBEA | c.6655C>T p.R2219C | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); catalogued as CM1515424, COSV59788909; called by muse, mutect2, varscan2
- NBEA | c.8309C>T p.P2770L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1450566339, COSV59776636; called by muse, mutect2, varscan2
- NCAM2 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV53078824; called by muse, mutect2, varscan2
- NCBP1 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 80/198 reads (40%) | catalogued as COSV64316851; called by muse, mutect2, varscan2
- NCK1 | c.531G>T p.E177D | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56637599; called by muse, mutect2, varscan2
- NCKAP5 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV58447028; called by muse, mutect2, varscan2
- NCKAP5 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264931730, COSV58447039; called by muse, mutect2, varscan2
- NCKAP5 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58447051; called by muse, mutect2, varscan2
- NCOA1 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV56045258; called by muse, mutect2, varscan2
- NCOA1 | c.2274A>C p.K758N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV56045282; called by muse, mutect2, varscan2
- NCOA7 | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.019); catalogued as rs888098479, COSV57652674; called by muse, mutect2, varscan2
- NEB | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51422170; called by muse, mutect2, varscan2
- NEK11 | c.1460G>A p.C487Y | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV67281369; called by muse, mutect2, varscan2
- NEK5 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 126/311 reads (41%) | catalogued as COSV100839182, COSV62880189; called by muse, mutect2, varscan2
- NEUROD4 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.173); catalogued as COSV54472005; called by muse, mutect2, varscan2
- NEXMIF | c.4480A>C p.K1494Q | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV50035937; called by muse, mutect2, varscan2
- NFIL3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs34945709; called by muse, mutect2, varscan2
- NFIL3 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.378); catalogued as COSV99906830; called by muse, mutect2
- NFKB1 | c.2051C>T p.S684F (on ENST00000394820 / NM_001382627.1; = p.S685F on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56957137; called by muse, mutect2, varscan2
- NHLRC1 | c.758G>T p.R253I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as CM054017, COSV61481559; called by muse, mutect2, varscan2
- NOBOX | c.864G>T p.E288D | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56194926; called by muse, mutect2, varscan2
- NOC3L | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 175/459 reads (38%) | catalogued as COSV64929653; called by muse, mutect2, varscan2
- NPY5R | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1320973552, COSV58452252; called by muse, mutect2, varscan2
- NRBF2 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs765677980, COSV53259401; called by muse, mutect2, varscan2
- NRG3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64565074; called by muse, mutect2, varscan2
- NRK | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54593617, COSV54598004; called by muse, mutect2, varscan2
- NRK | c.4580C>A p.S1527Y | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99686938; called by muse, mutect2
- NRXN3 | c.2460G>T p.E820D (on ENST00000335750 / NM_001330195.2; = p.E447D on NM_004796.6) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV59755947; called by muse, mutect2, varscan2
- NSFL1C | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV53792712; called by muse, mutect2, varscan2
- NSFL1C | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs756406410, COSV53792627; called by muse, mutect2, varscan2
- NSUN7 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 81/214 reads (38%) | catalogued as COSV57274199; called by muse, mutect2, varscan2
- NUP210L | c.2389G>T p.V797F | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV55148950; called by muse, mutect2, varscan2
- NUP42 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs763615256, COSV51729851; called by muse, mutect2, varscan2
- NUP93 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV57431275; called by muse, mutect2, varscan2
- NUTM1 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100412180; called by muse, mutect2
- ODF2L | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV54015808; called by muse, mutect2, varscan2
- OGT | c.2318A>T p.N773I | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.03); catalogued as COSV65480938; called by muse, mutect2, varscan2
- OLFML2B | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as COSV99668151; called by muse, mutect2
- OMA1 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV62255670; called by muse, mutect2, varscan2
- OR1N2 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs748161224, COSV65460748; called by muse, mutect2, varscan2
- OR2C1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs146842001; called by muse, mutect2, varscan2
- OR4A15 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs772757204, COSV59035578; called by muse, mutect2, varscan2
- OR4A15 | c.673A>C p.T225P | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV59034110, COSV59037616; called by muse, mutect2, varscan2
- OR4C12 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV58860171; called by muse, mutect2, varscan2
- OR4P4 | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 90/103 reads (87%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as rs746906978, COSV58920906, COSV58922157; called by muse, mutect2, varscan2
- OR51S1 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59057209, COSV59058640; called by muse, mutect2, varscan2
- OR52A1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs747955134, COSV100200481, COSV61092361; called by muse, mutect2, varscan2
- OR52A5 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56614160; called by muse, mutect2, varscan2
- OR52B6 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61447205; called by muse, mutect2, varscan2
- OR52K2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 152/396 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV57835175; called by muse, mutect2, varscan2
- OR5AN1 | c.542A>G p.D181G | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369767691, COSV58322249; called by muse, mutect2, varscan2
- OR5K1 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV60303715; called by muse, mutect2, varscan2
- OR5K1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60304367, COSV60304401; called by muse, mutect2, varscan2
- OR7A10 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs771110371, COSV50166188; called by muse, mutect2, varscan2
- OR8G1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.116); catalogued as COSV58381338; called by muse, varscan2
- OSR1 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55345684; called by muse, mutect2, varscan2
- OTUD3 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64295719; called by muse, mutect2, varscan2
- OTUD4 | c.1114A>C p.K372Q (on ENST00000447906 / NM_001366057.1; = p.K307Q on NM_001102653.1) | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV71381914; called by muse, mutect2, varscan2
- OVCH1 | c.3303G>T p.K1101N | Missense Mutation (SNP) | VAF 124/358 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); catalogued as COSV58963529, COSV58966227; called by muse, mutect2, varscan2
- OVCH1 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV58963537; called by muse, mutect2, varscan2
- P4HA1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 100/200 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV54961948; called by muse, mutect2, varscan2
- PABPC1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs748141355, COSV59402073; called by muse, mutect2, varscan2
- PAMR1 | c.2129C>A p.P710H (on ENST00000619888 / NM_001001991.3; = p.P727H on NM_015430.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV53513074; called by muse, mutect2, varscan2
- PAPSS1 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99491850; called by muse, mutect2
- PAQR6 | c.453C>A p.F151L (on ENST00000292291 / NM_001272108.2; = p.F45L on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs144076256; called by mutect2, varscan2
- PARP4 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV67962264, COSV67964067; called by muse, mutect2, varscan2
- PARVB | c.711C>T p.F237= | Splice Region (SNP) | VAF 110/288 reads (38%) | catalogued as rs149571024; called by muse, mutect2, varscan2
- PCDH15 | c.5313G>T p.K1771N | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious, low confidence (0.01); catalogued as COSV64699001; called by muse, mutect2, varscan2
- PCDH15 | c.4440A>C p.Q1480H | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV57321671; called by muse, mutect2, varscan2
- PCDH15 | c.2490G>T p.E830D | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375318219; called by muse, mutect2, varscan2
- PCDH15 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs960966107, COSV57321722; called by muse, mutect2, varscan2
- PCDH18 | c.1937C>A p.S646Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs144644832, COSV61266900, COSV61268896; called by muse, mutect2, varscan2
- PCDH9 | c.3690G>T p.E1230D (on ENST00000377865 / NM_203487.3; = p.E1196D on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60555220; called by muse, mutect2, varscan2
- PCDHB4 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.088); catalogued as COSV52023158; called by muse, mutect2, varscan2
- PCDHGA1 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100965942; called by muse, mutect2
- PCDHGA6 | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.034); catalogued as COSV53960602; called by muse, mutect2, varscan2
- PCDHGB3 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1561547242, COSV53913586; called by muse, mutect2, varscan2
- PCGF5 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs777571971, COSV60238136; called by muse, mutect2, varscan2
- PCLO | c.7946C>A p.S2649Y | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV61639050; called by muse, mutect2, varscan2
- PCNX1 | c.4015C>T p.R1339* | Nonsense Mutation (SNP) | VAF 89/262 reads (34%) | catalogued as COSV53092089; called by muse, mutect2, varscan2
- PCSK5 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1182507599, COSV65089807, COSV65097584; called by muse, mutect2, varscan2
- PDE10A | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1486730580, COSV100605223, COSV63097743; called by muse, mutect2, varscan2
- PDE3A | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs758486260, COSV62974263; called by muse, mutect2, varscan2
- PDE8B | c.1915A>C p.S639R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV53738559; called by muse, mutect2, varscan2
- PDGFD | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 125/320 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56379928; called by muse, mutect2, varscan2
- PDHA1 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV63327810; called by muse, varscan2
- PDK1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 85/196 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs758355812, COSV56375591; called by muse, mutect2, varscan2
- PDZRN4 | c.1129G>T p.E377* (on ENST00000402685 / NM_001164595.2; = p.E119* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV54203500; called by muse, mutect2, varscan2
- PER2 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 75/590 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV54524238, COSV54525048; called by muse, mutect2, varscan2
- PEX1 | c.3823C>T p.R1275* | Nonsense Mutation (SNP) | VAF 90/227 reads (40%) | catalogued as rs755549316, COSV50399683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKFB1 | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 44/100 reads (44%) | PolyPhen probably damaging (0.991); catalogued as COSV66628515; called by muse, mutect2, varscan2
- PGS1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213255033, COSV53144140, COSV53147402; called by muse, mutect2, varscan2
- PHF23 | c.115A>C p.S39R | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV50036401; called by muse, mutect2, varscan2
- PHIP | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51505236; called by muse, mutect2, varscan2
- PIGW | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs766615427; called by muse, mutect2, varscan2
- PIK3C2B | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65811235; called by muse, mutect2, varscan2
- PIK3R5 | c.2191A>T p.I731F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV52654514; called by muse, mutect2
- PIKFYVE | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866761146, COSV100011010, COSV52237901; called by muse, mutect2, varscan2
- PKHD1L1 | c.12128C>T p.S4043L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as rs761556541, COSV65736646; called by muse, mutect2, varscan2
- PLA2G4C | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.204); catalogued as COSV62785758; called by muse, mutect2, varscan2
- PLA2R1 | c.2691G>T p.Q897H | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51779787; called by muse, mutect2, varscan2
- PLAC8L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 60/157 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100268682; called by muse, mutect2
- PLAU | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as COSV65641467; called by muse, mutect2, varscan2
- PLCL1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750894486, COSV70825024; called by muse, mutect2, varscan2
- PLEKHG4 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs746720610, COSV64612947; called by muse, mutect2, varscan2
- PLS1 | c.1422C>A p.F474L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV61834075; called by muse, mutect2, varscan2
- PLXNC1 | c.3619A>C p.K1207Q | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs765020076, COSV51576246; called by muse, mutect2, varscan2
- PNLIPRP3 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 161/429 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV65048369; called by muse, mutect2, varscan2
- PNPLA1 | c.1372G>T p.E458* (on ENST00000394571 / NM_001374623.1; = p.E363* on NM_173676.2) | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV57234752; called by muse, mutect2, varscan2
- POLA1 | c.385A>G p.T129A | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV66886839; called by muse, mutect2, varscan2
- POLE | c.1331T>A p.M444K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57675126; called by muse, mutect2, varscan2
- POLR1A | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55693928; called by muse, mutect2, varscan2
- PON1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs749649413, COSV55930537; called by muse, mutect2, varscan2
- POSTN | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770865489, COSV65713203; called by muse, mutect2, varscan2
- POTEE | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 147/379 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58224851; called by muse, mutect2, varscan2
- POTEF | c.2022G>T p.K674N | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs761759443, COSV100665247, COSV62539689; called by muse, mutect2, varscan2
- POU2F2 | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs760733530, COSV60762740; called by muse, mutect2, varscan2
- POU3F2 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV60409003; called by muse, mutect2, varscan2
- PPEF2 | c.865C>A p.L289I | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54422870; called by muse, mutect2, varscan2
- PPIE | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60971827; called by muse, mutect2, varscan2
- PPIH | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 28/274 reads (10%) | catalogued as rs375438488, COSV100501152; called by muse, mutect2, varscan2
689 further variants in this file (442 protein-altering or splice-affecting, 207 silent, 40 other) are not listed here.
